CCDI case PBCEWU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/84c71514-f5ad-4aac-8efb-ad9e918f1365

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Pinealoma: ICD-O-3 morphology code: 9360/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.0 years (2,908 days).

Biospecimens (3 samples)
- Sample 0DRCJT: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DRCJV: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DRCK1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
